Somatic mutation profile of tumor specimen 0DHKQC from CCDI case PBBUEV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Embryonal rhabdomyosarcoma, NOS; Tissue or organ of origin: Anterior wall of nasopharynx; Age at diagnosis: 10.1 years (3,702 days).
Specimen 0DHKQC: Tissue type: Tumor; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9c303a6-9ece-4f7b-ad1f-28b3a53659af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHKP3 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c42f3a27-097b-44d4-8c30-79c996becd03

The open-access MAF lists 85 somatic variants for this specimen: 48 protein-altering or splice-affecting, 19 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, Silent 19, Intron 13, Nonsense Mutation 4, 3'UTR 2, Splice Region 2, 5'UTR 2, Frame Shift Del 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADGRG6 | c.2303A>T p.Y768F | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.098); catalogued as rs1290197016; called by muse, mutect2
- BCOR | c.4390G>C p.E1464Q (on ENST00000378444 / NM_001123385.2; = p.E1430Q on NM_017745.6) | Missense Mutation (SNP) | VAF 173/184 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV60698491, COSV60722901; called by muse, mutect2, varscan2
- BRCA1 | c.1543G>A p.E515K | Missense Mutation (SNP) | VAF 24/437 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs886037990, COSV100524285, COSV58784706, COSV58788589; ClinVar: uncertain significance; called by muse, mutect2
- CPSF7 | c.1387C>T p.R463W (on ENST00000394888 / NM_001136040.4; = p.R506W on NM_024811.4) | Missense Mutation (SNP) | VAF 133/404 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100467102; called by muse, mutect2, varscan2
- GABRA1 | c.553G>C p.G185R | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50101979, COSV50106468; called by muse, mutect2
- HAPLN4 | c.816G>A p.P272= | Splice Region (SNP) | VAF 60/164 reads (37%) | catalogued as rs767885551, COSV52270450, COSV99363723; called by muse, mutect2, varscan2
- IGF1R | c.1302G>A p.W434* | Nonsense Mutation (SNP) | VAF 44/472 reads (9%) | catalogued as COSV51368461; called by muse, mutect2
- IGSF10 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 123/239 reads (51%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.939); catalogued as rs369529396; called by muse, mutect2, varscan2
- KCND3 | c.523A>G p.N175D | Missense Mutation (SNP) | VAF 63/172 reads (37%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as COSV100137074; called by muse, mutect2, varscan2
- KCNJ4 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 97/237 reads (41%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.011); catalogued as rs1177521446; called by muse, mutect2, varscan2
- MYH1 | c.2884G>T p.E962* | Nonsense Mutation (SNP) | VAF 67/235 reads (29%) | catalogued as COSV99876131; called by muse, mutect2, varscan2
- NKX6-1 | c.1052G>A p.G351D | Missense Mutation (SNP) | VAF 36/297 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.021); catalogued as rs764349799; called by muse, mutect2, varscan2
- PXDNL | c.379C>T p.L127= | Splice Region (SNP) | VAF 36/598 reads (6%) | catalogued as rs779645881, COSV62486729; called by muse, mutect2
- SKOR1 | c.1895G>A p.G632D | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs919230692; called by muse, mutect2, varscan2
- TET2 | c.248G>A p.R83K | Missense Mutation (SNP) | VAF 138/344 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV54398310; called by muse, mutect2, varscan2
- TP53 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 98/126 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52795913, COSV52851768, COSV52978286; called by muse, mutect2, varscan2
- USF2 | c.1016T>C p.M339T | Missense Mutation (SNP) | VAF 80/209 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs747530101; called by muse, mutect2, varscan2
- ZNF439 | c.1437G>T p.Q479H | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV58309234; called by muse, mutect2, varscan2
- ZSCAN16 | c.827G>A p.R276H | Missense Mutation (SNP) | VAF 34/311 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs771364627; called by muse, mutect2, varscan2
- ADAM29 | c.892A>C p.S298R | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.142); called by muse, mutect2
- C2CD4A | c.773G>T p.R258L | Missense Mutation (SNP) | VAF 53/115 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); called by muse, mutect2, varscan2
- CCDC170 | c.1750A>C p.N584H | Missense Mutation (SNP) | VAF 81/447 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- CDC73 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CTNND2 | c.1391T>A p.V464D | Missense Mutation (SNP) | VAF 16/574 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2
- CXorf21 | c.283C>A p.P95T | Missense Mutation (SNP) | VAF 94/102 reads (92%) | SIFT tolerated (0.13); PolyPhen benign (0.288); called by muse, varscan2
- DHRS12 | c.875del p.L292Pfs*52 | Frame Shift Del (DEL) | VAF 136/438 reads (31%) | called by mutect2, varscan2
- ESR1 | c.56A>G p.Q19R | Missense Mutation (SNP) | VAF 37/268 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- EYS | c.3898G>T p.V1300F | Missense Mutation (SNP) | VAF 103/394 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFRA3 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 83/173 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- GRHL1 | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 77/848 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H3C2 | c.171G>C p.K57N | Missense Mutation (SNP) | VAF 143/367 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- HLA-DPB1 | c.599G>T p.C200F | Missense Mutation (SNP) | VAF 88/536 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HROB | c.1336G>A p.E446K | Missense Mutation (SNP) | VAF 145/300 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- LETM2 | c.553T>A p.L185I (on ENST00000379957 / NM_001286819.2; = p.L138I on NM_001199659.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/667 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NEO1 | c.4313C>A p.P1438Q | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated (0.84); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- NRXN2 | c.1585C>A p.L529M | Missense Mutation (SNP) | VAF 98/458 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PARP14 | c.4851C>G p.F1617L | Missense Mutation (SNP) | VAF 167/389 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKHD1 | c.9541G>C p.A3181P | Missense Mutation (SNP) | VAF 108/322 reads (34%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLS1 | c.796C>T p.L266F | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PLXNA1 | c.4547C>A p.P1516H | Missense Mutation (SNP) | VAF 158/403 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- PUM1 | c.10G>C p.A4P | Missense Mutation (SNP) | VAF 32/145 reads (22%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- RCOR2 | c.119_122del p.H40Rfs*5 | Frame Shift Del (DEL) | VAF 82/270 reads (30%) | called by mutect2, varscan2
- RIPOR3 | c.1981G>C p.E661Q | Missense Mutation (SNP) | VAF 364/813 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.408); called by muse, mutect2, varscan2
- SLC5A11 | c.937G>T p.A313S | Missense Mutation (SNP) | VAF 136/338 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- TMEM132B | c.2030C>A p.A677E | Missense Mutation (SNP) | VAF 176/461 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- TMEM87B | c.577A>C p.S193R | Missense Mutation (SNP) | VAF 69/451 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TREH | c.977G>A p.W326* | Nonsense Mutation (SNP) | VAF 48/672 reads (7%) | called by muse, mutect2
- UNC80 | c.3859C>T p.R1287* | Nonsense Mutation (SNP) | VAF 198/280 reads (71%) | called by muse, mutect2, varscan2
- ADGRB3 | c.4389C>A p.P1463= | Silent (SNP) | VAF 101/251 reads (40%) | catalogued as rs755776819; called by muse, mutect2, varscan2
- ALPK2 | c.2928C>A p.A976= | Silent (SNP) | VAF 264/421 reads (63%) | called by mutect2, varscan2
- HR | c.661T>C p.L221= | Silent (SNP) | VAF 68/1213 reads (6%) | called by muse, mutect2
- KHNYN | c.1909C>A p.R637= | Silent (SNP) | VAF 118/257 reads (46%) | called by muse, mutect2, varscan2
- KRT71 | c.630G>A p.R210= | Silent (SNP) | VAF 202/672 reads (30%) | called by muse, mutect2, varscan2
- KRT84 | c.1527C>A p.R509= | Silent (SNP) | VAF 148/471 reads (31%) | catalogued as rs915525628; called by muse, mutect2, varscan2
- MUC22 | c.1515C>A p.T505= | Silent (SNP) | VAF 40/389 reads (10%) | called by mutect2, varscan2
- NBEAL1 | c.4035A>G p.P1345= | Silent (SNP) | VAF 18/608 reads (3%) | called by muse, mutect2
- ONECUT1 | c.540G>T p.S180= | Silent (SNP) | VAF 40/102 reads (39%) | catalogued as rs140790810, COSV59949943; called by muse, mutect2, varscan2
- PPP1R13L | c.1128C>T p.F376= | Silent (SNP) | VAF 152/182 reads (84%) | called by muse, mutect2, varscan2
- RAD51AP2 | c.3420T>C p.I1140= | Silent (SNP) | VAF 140/489 reads (29%) | called by muse, mutect2, varscan2
- TECRL | c.570T>C p.H190= | Silent (SNP) | VAF 79/193 reads (41%) | called by muse, mutect2, varscan2
- TG | c.525G>T p.V175= | Silent (SNP) | VAF 116/669 reads (17%) | called by muse, mutect2, varscan2
- TGM4 | c.1509T>C p.N503= | Silent (SNP) | VAF 17/540 reads (3%) | called by muse, mutect2
- TLL2 | c.2787C>T p.Y929= | Silent (SNP) | VAF 189/415 reads (46%) | catalogued as rs973244513, COSV100780368, COSV100780407; called by muse, mutect2, varscan2
- VAX2 | c.694C>T p.L232= | Silent (SNP) | VAF 51/488 reads (10%) | called by muse, mutect2, varscan2
- ZBTB46 | c.195G>A p.K65= | Silent (SNP) | VAF 110/427 reads (26%) | called by muse, mutect2, varscan2
- ZNF334 | c.249T>C p.D83= | Silent (SNP) | VAF 28/733 reads (4%) | called by muse, mutect2
- ZNF638 | c.3051G>A p.P1017= | Silent (SNP) | VAF 100/432 reads (23%) | catalogued as rs144453296; called by muse, mutect2, varscan2
- ADD3 | c.1144-20G>T | Intron (SNP) | VAF 8/91 reads (9%) | called by muse, mutect2
- AMHR2 | c.1425+31C>G | Intron (SNP) | VAF 44/180 reads (24%) | called by muse, mutect2, varscan2
- CNBD1 | c.431+9T>G | Intron (SNP) | VAF 82/208 reads (39%) | called by mutect2, varscan2
- CNBD1 | c.431+14del | Intron (DEL) | VAF 74/200 reads (37%) | called by mutect2, varscan2
- DCHS2 | n.3756C>A | RNA (SNP) | VAF 171/429 reads (40%) | called by muse, mutect2, varscan2
- DUS1L | c.698-67C>A | Intron (SNP) | VAF 83/420 reads (20%) | called by muse, mutect2, varscan2
- DYSF | c.3874-24C>A | Intron (SNP) | VAF 205/324 reads (63%) | called by muse, mutect2, varscan2
- ECPAS | c.-144G>A | 5'UTR (SNP) | VAF 15/192 reads (8%) | catalogued as rs751589475; called by muse, mutect2
- EXOSC10 | c.111+22G>T | Intron (SNP) | VAF 37/261 reads (14%) | called by muse, mutect2, varscan2
- GRIK1 | c.1206+36A>C | Intron (SNP) | VAF 61/229 reads (27%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.361-29C>A | Intron (SNP) | VAF 63/570 reads (11%) | called by mutect2, varscan2
- MSANTD4 | c.-73G>T | 5'UTR (SNP) | VAF 49/183 reads (27%) | called by muse, mutect2, varscan2
- NEB | c.8890-2872T>G | Intron (SNP) | VAF 170/590 reads (29%) | called by muse, mutect2, varscan2
- PTK2B | c.*25C>T | 3'UTR (SNP) | VAF 58/369 reads (16%) | catalogued as rs1364831225; called by muse, mutect2, varscan2
- SARS2 | c.393+37G>A | Intron (SNP) | VAF 123/378 reads (33%) | catalogued as rs372505077; called by muse, mutect2, varscan2
- STK3 | c.1317+65G>T | Intron (SNP) | VAF 12/100 reads (12%) | called by muse, mutect2
- VAT1L | c.*52G>A | 3'UTR (SNP) | VAF 32/86 reads (37%) | catalogued as rs1289262677; called by muse, varscan2
- WDPCP | c.2159-23A>T | Intron (SNP) | VAF 32/244 reads (13%) | called by muse, mutect2, varscan2
